Somatic mutation profile of tumor specimen MMRF_1587_1_BM_CD138pos (aliquot MMRF_1587_1_BM_CD138pos_T1_KBS5U_L04120) from MMRF case MMRF_1587, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,232 days).
Specimen MMRF_1587_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9ae1435-8a91-46c3-b165-91723fda72c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1587_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1587_1_PB_CD3pos_C2_KBS5U_L04126; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/338cee99-5402-4c9f-aa51-9087127d7658

The open-access MAF lists 235 somatic variants for this specimen: 95 protein-altering or splice-affecting, 29 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, 3'UTR 65, Silent 29, Intron 26, Nonsense Mutation 12, 5'UTR 7, Frame Shift Del 6, 3'Flank 5, RNA 5, 5'Flank 3, Splice Site 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 133/365 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100086450; called by muse, mutect2, varscan2
- BICDL1 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs780597636; called by muse, mutect2, varscan2
- CD74 | c.125+1G>A p.X42_splice | Splice Site (SNP) | VAF 54/96 reads (56%) | catalogued as rs112138942; called by muse, mutect2, varscan2
- CDH8 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866984859, COSV54865725; called by muse, mutect2, varscan2
- CHST12 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs905098497, COSV51676142; called by muse, mutect2, varscan2
- CNTNAP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100671653; called by muse, mutect2, varscan2
- CYP27B1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs763451961, COSV57348930; called by muse, mutect2, varscan2
- GTPBP8 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 186/386 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs779918051; called by mutect2, varscan2
- H1-5 | c.266G>C p.S89T | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100137908; called by muse, mutect2
- HYDIN | c.7574G>A p.R2525H | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756437118, COSV59262649; called by muse, mutect2, varscan2
- IBTK | c.2121dup p.G708Rfs*5 | Frame Shift Ins (INS) | VAF 75/184 reads (41%) | catalogued as rs772241425; called by mutect2, pindel, varscan2
- IGHV1-69 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | catalogued as rs558289670; called by mutect2, varscan2
- IGHV2-70 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570255228; called by muse, mutect2, varscan2
- IGHV3-33 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs752557018; called by muse, varscan2
- IGKV4-1 | c.354T>G p.Y118* | Nonsense Mutation (SNP) | VAF 36/38 reads (95%) | catalogued as rs374092750; called by muse, mutect2, varscan2
- KANSL1 | c.902T>A p.L301* | Nonsense Mutation (SNP) | VAF 112/229 reads (49%) | catalogued as rs1189248208; called by muse, mutect2, varscan2
- KCNG1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs368678625; called by muse, mutect2, varscan2
- LNX1 | c.844C>G p.P282A (on ENST00000263925 / NM_001126328.3; = p.P186A on NM_032622.2) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV55785915; called by muse, mutect2, varscan2
- MSLNL | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV53507123; called by muse, mutect2, varscan2
- MYO15A | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV52753225; called by muse, mutect2, varscan2
- PCDH8 | c.2050C>A p.R684S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.439); catalogued as rs1290037589; called by muse, mutect2, varscan2
- PCDHB6 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 120/324 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs904708904, COSV50695334; called by muse, mutect2, varscan2
- PML | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1247431420; called by muse, mutect2, varscan2
- PRG3 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs752005955; called by muse, mutect2, varscan2
- PRKD1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 92/94 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201010570, COSV100119643; called by muse, mutect2, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 107/120 reads (89%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2
- PTPRU | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774083255; called by muse, mutect2, varscan2
- ROBO3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101185218; called by muse, mutect2, varscan2
- SERINC2 | c.433G>A p.V145M (on ENST00000373709 / NM_178865.5; = p.V149M on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/365 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140666908; called by muse, mutect2, varscan2
- SLC2A3 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs1197154662; called by muse, mutect2, varscan2
- SP140 | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as rs190133390; called by muse, mutect2, varscan2
- SPATA31D1 | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV61202480; called by muse, mutect2
- ST6GALNAC1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | PolyPhen possibly damaging (0.72); catalogued as rs757163221; called by muse, mutect2, varscan2
- TADA3 | c.810G>A p.E270= | Splice Region (SNP) | VAF 35/65 reads (54%) | catalogued as rs1277993137, COSV57333420; called by muse, mutect2, varscan2
- TDRD15 | c.5451T>A p.Y1817* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | catalogued as rs1486876855; called by muse, mutect2
- ANO3 | c.1991T>C p.V664A | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASB3 | c.893T>A p.I298K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- BHLHE41 | c.998_1028del p.G333Afs*160 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | called by mutect2, pindel
- BICC1 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 81/95 reads (85%) | called by muse, mutect2, varscan2
- BTBD3 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- CDH11 | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CDH9 | c.473A>T p.K158I | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- CDK13 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CEP43 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- CHRM2 | c.948A>C p.K316N | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DST | c.6273A>C p.E2091D | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EBF3 | c.809C>G p.P270R (on ENST00000355311 / NM_001375392.1; = p.P261R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECHDC1 | c.406A>C p.M136L (on ENST00000531967 / NM_001139510.1; = p.M130L on NM_001002030.2) | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ECT2L | c.2384G>A p.C795Y | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP400 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- FOXQ1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRRS1L | c.767T>A p.I256N | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR142 | c.1177del p.H393Tfs*58 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPU | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 28/552 reads (5%) | called by muse, mutect2
- IGHV2-70D | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, varscan2
- IGHV2-70D | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 56/58 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV2-70D | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGKV4-1 | c.219_226del p.I74Gfs*10 | Frame Shift Del (DEL) | VAF 33/42 reads (79%) | called by pindel, varscan2
- INO80D | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 68/146 reads (47%) | called by muse, mutect2, varscan2
- IQGAP3 | c.2427A>C p.Q809H | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.353); called by muse, mutect2
- JAK1 | c.2970G>C p.G990= | Splice Region (SNP) | VAF 129/281 reads (46%) | called by muse, mutect2, varscan2
- KCNMB4 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2E | c.4381C>T p.Q1461* | Nonsense Mutation (SNP) | VAF 29/487 reads (6%) | called by muse, mutect2
- L2HGDH | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LONRF1 | c.2013del p.E672Rfs*27 | Frame Shift Del (DEL) | VAF 37/79 reads (47%) | called by mutect2, pindel, varscan2
- LRRD1 | c.762A>T p.E254D | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MED12L | c.3872T>C p.I1291T | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MGAT4C | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MMP13 | c.1164_1170del p.F388Lfs*30 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | called by mutect2, pindel, varscan2
- MRM1 | c.636+1G>C p.X212_splice | Splice Site (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- NOL6 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- OR14A2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 476/515 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PCDHA8 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); called by muse, mutect2
- PLEKHG4 | c.725A>C p.E242A | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POU3F4 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 79/80 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R26 | c.2972G>C p.G991A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- PRKCA | c.1294G>C p.V432L | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS22 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- REM1 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- REX1BD | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGMA | c.696C>A p.Y232* | Nonsense Mutation (SNP) | VAF 132/288 reads (46%) | called by muse, mutect2, varscan2
- RLF | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHANK1 | c.4938T>A p.H1646Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SP140 | c.2400del p.W800Cfs*9 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | called by mutect2, pindel
- SPANXB1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SPOCD1 | c.1432T>G p.S478A | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- ST6GALNAC6 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- STARD4 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TCF19 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TG | c.8233T>G p.L2745V | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TYRP1 | c.1409-7_1409-2del p.X470_splice | Splice Site (DEL) | VAF 77/192 reads (40%) | called by mutect2, pindel, varscan2
- UMODL1 | c.3866C>A p.T1289N (on ENST00000408910 / NM_001004416.2; = p.T1417N on NM_173568.3) | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- VWA8 | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZNFX1 | c.999C>G p.Y333* | Nonsense Mutation (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- ABCA2 | c.5937C>T p.F1979= (on ENST00000614293; = p.F1949= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV55801708; called by muse, mutect2, varscan2
- ALOX5 | c.969C>T p.P323= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- ALPI | c.798G>A p.V266= | Silent (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- ARR3 | c.252A>T p.P84= | Silent (SNP) | VAF 103/129 reads (80%) | called by muse, mutect2, varscan2
- ATP13A4 | c.2781C>T p.S927= | Silent (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- B3GAT2 | c.723C>T p.A241= | Silent (SNP) | VAF 115/228 reads (50%) | called by muse, mutect2, varscan2
- C1orf21 | c.180A>G p.Q60= | Silent (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- CEACAM7 | c.501C>T p.T167= | Silent (SNP) | VAF 77/154 reads (50%) | called by muse, mutect2, varscan2
- CEP112 | c.234G>A p.A78= | Silent (SNP) | VAF 87/210 reads (41%) | catalogued as rs182724164; called by muse, mutect2, varscan2
- COL25A1 | c.24G>T p.G8= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV67649814; called by muse, mutect2, varscan2
- FUT8 | c.1527C>T p.A509= (on ENST00000360689 / NM_001371534.1; = p.A346= on NM_004480.4) | Silent (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.942C>T p.R314= | Silent (SNP) | VAF 18/23 reads (78%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.144T>C p.S48= | Silent (SNP) | VAF 38/38 reads (100%) | catalogued as rs189675840; called by muse, varscan2
- ITPRIPL2 | c.9G>A p.V3= | Silent (SNP) | VAF 59/96 reads (61%) | called by muse, mutect2, varscan2
- KDR | c.3801A>G p.E1267= | Silent (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- MAP3K4 | c.1404T>C p.D468= | Silent (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- MEN1 | c.1272C>T p.G424= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV53646697; called by muse, mutect2, varscan2
- MSR1 | c.882A>C p.G294= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- NIBAN2 | c.480C>A p.L160= | Silent (SNP) | VAF 58/109 reads (53%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.216G>A p.L72= | Silent (SNP) | VAF 400/422 reads (95%) | called by muse, mutect2, varscan2
- PCDHGC3 | c.792A>G p.V264= | Silent (SNP) | VAF 137/319 reads (43%) | catalogued as rs754076231; called by muse, mutect2, varscan2
- PPARGC1B | c.2343C>A p.A781= | Silent (SNP) | VAF 67/115 reads (58%) | called by muse, mutect2, varscan2
- RGS22 | c.3102A>G p.Q1034= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs374356639; called by muse, mutect2, varscan2
- SKOR1 | c.2817C>T p.A939= | Silent (SNP) | VAF 78/193 reads (40%) | catalogued as rs748947613; called by muse, mutect2, varscan2
- SMC1A | c.651A>T p.V217= | Silent (SNP) | VAF 84/87 reads (97%) | called by muse, mutect2, varscan2
- SMIM9 | c.51T>C p.T17= | Silent (SNP) | VAF 248/250 reads (99%) | called by muse, mutect2, varscan2
- TCF4 | c.174C>T p.S58= | Silent (SNP) | VAF 65/133 reads (49%) | called by muse, mutect2, varscan2
- TTC8 | c.246G>A p.T82= (on ENST00000338104 / NM_001288781.1; = p.T92= on NM_144596.4) | Silent (SNP) | VAF 78/78 reads (100%) | catalogued as rs574914287; called by muse, mutect2, varscan2
- WDR72 | c.1617G>A p.V539= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- ABCB1 | c.*171C>T | 3'UTR (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- ABCC13 | n.3965C>T | RNA (SNP) | VAF 70/151 reads (46%) | catalogued as rs983835409; called by muse, mutect2, varscan2
- AC020688.1 | chr8:127087565 A>G | 5'Flank (SNP) | VAF 10/102 reads (10%) | catalogued as rs1440279862; called by muse, mutect2, varscan2
- ACSM5 | c.*858dup | 3'UTR (INS) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- ACTR1B | c.-106C>A | 5'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.-151+1813G>A | Intron (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- AGPAT1 | c.*1001G>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs147503745; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4932G>T | Intron (SNP) | VAF 73/168 reads (43%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73828042 G>C | 3'Flank (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- AL441992.2 | c.*276C>A | 3'UTR (SNP) | VAF 74/139 reads (53%) | called by muse, mutect2, varscan2
- AMBRA1 | c.*385G>T | 3'UTR (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- ANTXR1 | c.952-6788G>C | Intron (SNP) | VAF 70/187 reads (37%) | called by muse, varscan2
- ANTXR1 | c.952-6738G>C | Intron (SNP) | VAF 54/135 reads (40%) | catalogued as COSV100362308; called by muse, varscan2
- ANTXR1 | c.952-6577G>A | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- ANTXR1 | c.952-6395G>T | Intron (SNP) | VAF 28/76 reads (37%) | called by muse, varscan2
- ANTXR1 | c.952-6326G>C | Intron (SNP) | VAF 36/106 reads (34%) | catalogued as rs1268943075; called by muse, varscan2
- ANXA2R | c.-1174T>G | 5'UTR (SNP) | VAF 62/117 reads (53%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.535-189C>A | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- ASXL1 | c.719-430T>G | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs1298873293; called by muse, mutect2, varscan2
- ATL2 | c.*795A>G | 3'UTR (SNP) | VAF 72/176 reads (41%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*2257A>G | 3'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 69/136 reads (51%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BNC1 | c.*1273G>A | 3'UTR (SNP) | VAF 86/161 reads (53%) | called by muse, mutect2, varscan2
- C11orf40 | n.527G>A | RNA (SNP) | VAF 54/99 reads (55%) | catalogued as rs116086812, COSV56891862; called by muse, mutect2, varscan2
- C11orf87 | c.*1365dup | 3'UTR (INS) | VAF 55/138 reads (40%) | called by mutect2, pindel, varscan2
- C1orf216 | c.*498A>G | 3'UTR (SNP) | VAF 115/229 reads (50%) | called by muse, mutect2, varscan2
- CDK8 | c.456+5789G>C | Intron (SNP) | VAF 145/149 reads (97%) | called by muse, mutect2, varscan2
- CEP290 | c.1825-369A>G | Intron (SNP) | VAF 85/200 reads (43%) | called by muse, mutect2, varscan2
- CHTOP | c.541+566G>A | Intron (SNP) | VAF 162/201 reads (81%) | catalogued as rs1165251311; called by muse, mutect2, varscan2
- COA1 | c.-38-1094A>G | Intron (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- CYP4F24P | n.82C>A | RNA (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- DDIT4L | c.*1484C>T | 3'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- DENND3 | c.*1506A>T | 3'UTR (SNP) | VAF 43/122 reads (35%) | called by muse, mutect2, varscan2
- DGKD | c.157-2302C>T | Intron (SNP) | VAF 93/162 reads (57%) | catalogued as rs1362105583; called by muse, mutect2, varscan2
- DLK1 | c.-9C>T | 5'UTR (SNP) | VAF 33/42 reads (79%) | called by muse, mutect2, varscan2
- DMD | c.*689A>G | 3'UTR (SNP) | VAF 22/28 reads (79%) | called by muse, mutect2, varscan2
- DNM1L | c.*683_*684dup | 3'UTR (INS) | VAF 36/90 reads (40%) | called by mutect2, pindel, varscan2
- DTWD2 | c.*1762G>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, varscan2
- EFL1 | c.*107T>G | 3'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- EIF2S3 | c.*762C>A | 3'UTR (SNP) | VAF 48/305 reads (16%) | called by muse, mutect2, varscan2
- EIF4E | c.*2338T>C | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2
- EPHA5 | c.*823A>G | 3'UTR (SNP) | VAF 91/185 reads (49%) | called by muse, mutect2, varscan2
- FOXP1 | c.*3002C>T | 3'UTR (SNP) | VAF 72/144 reads (50%) | catalogued as rs566673921; called by muse, varscan2
- GABRA2 | c.187+18846dup | Intron (INS) | VAF 53/133 reads (40%) | catalogued as rs1435584240; called by mutect2, varscan2
- GATD1 | c.*747C>G | 3'UTR (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- GDAP2 | c.*381T>C | 3'UTR (SNP) | VAF 54/54 reads (100%) | called by muse, mutect2, varscan2
- GIMAP5 | c.*454T>C | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- HACE1 | c.*1273A>T | 3'UTR (SNP) | VAF 35/180 reads (19%) | called by muse, mutect2, varscan2
- HELLPAR | n.199289G>T | RNA (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- HNRNPLL | c.*899del | 3'UTR (DEL) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- HPCAL4 | c.*3728dup | 3'UTR (INS) | VAF 19/98 reads (19%) | catalogued as rs1282685802; called by mutect2, pindel, varscan2
- IBA57 | c.*106G>A | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- IGF2 | chr11:2129358 G>T | 3'Flank (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- KCNG3 | c.*1323C>G | 3'UTR (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- KSR1 | c.*1770del | 3'UTR (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- MAP1LC3B2 | c.*248T>A | 3'UTR (SNP) | VAF 56/113 reads (50%) | called by muse, mutect2, varscan2
- MAP9 | c.*2320A>T | 3'UTR (SNP) | VAF 56/114 reads (49%) | called by mutect2, varscan2
- MARK4 | c.1494+178A>G | Intron (SNP) | VAF 100/201 reads (50%) | catalogued as rs1215186278; called by muse, mutect2, varscan2
- MCM3AP | c.4290+1894del | Intron (DEL) | VAF 79/184 reads (43%) | called by mutect2, pindel, varscan2
- MCUB | c.*508A>G | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- MCUB | c.*509A>T | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- MLEC | c.-111C>T | 5'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- MLLT11 | c.*242C>G | 3'UTR (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- MRNIP | c.537+1199G>C | Intron (SNP) | VAF 81/151 reads (54%) | called by muse, mutect2, varscan2
- MYO5A | c.*908G>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- NCAM2 | c.*2758A>C | 3'UTR (SNP) | VAF 79/150 reads (53%) | called by muse, mutect2, varscan2
- NIN | chr14:50721463 A>C | 3'Flank (SNP) | VAF 25/28 reads (89%) | catalogued as COSV55396857; called by muse, mutect2
- NIPBL | c.*950T>A | 3'UTR (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3582C>T | Intron (SNP) | VAF 80/182 reads (44%) | catalogued as rs961401016; called by muse, mutect2, varscan2
- NT5DC1 | c.*885A>C | 3'UTR (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- NTRK3 | c.*10610del | 3'UTR (DEL) | VAF 100/236 reads (42%) | called by mutect2, pindel, varscan2
- NUGGC | c.*796T>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- NUMA1 | c.129-78G>C | Intron (SNP) | VAF 29/101 reads (29%) | catalogued as rs997501126; called by muse, mutect2, varscan2
- PAX1 | c.*827A>T | 3'UTR (SNP) | VAF 51/119 reads (43%) | catalogued as rs1213145982; called by muse, mutect2, varscan2
- PAX6 | chr11:31789206 G>T | 3'Flank (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- PIGX | c.-99T>G | 5'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2962T>C | RNA (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4194G>A | 3'UTR (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2
- POLR3G | chr5:90514204 C>T | 3'Flank (SNP) | VAF 43/102 reads (42%) | catalogued as rs1267736954; called by muse, mutect2, varscan2
- PUDP | c.*104G>C | 3'UTR (SNP) | VAF 23/26 reads (88%) | called by muse, mutect2, varscan2
- RBBP5 | c.*470A>C | 3'UTR (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- ROR1 | c.*1322A>G | 3'UTR (SNP) | VAF 91/204 reads (45%) | called by muse, mutect2, varscan2
- RPS29 | c.-8A>C | 5'UTR (SNP) | VAF 85/108 reads (79%) | called by muse, mutect2, varscan2
- RTP1 | c.*197G>T | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- SCN11A | c.387-13G>A | Intron (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- SCN2B | c.*3091T>G | 3'UTR (SNP) | VAF 81/178 reads (46%) | called by muse, mutect2, varscan2
- SCN4B | c.*1856C>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- SEMA3D | c.*584G>C | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- SLC37A4 | c.984+215T>G | Intron (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*4790A>T | 3'UTR (SNP) | VAF 80/167 reads (48%) | called by muse, mutect2, varscan2
- SLC6A7 | c.*789G>A | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- SP4 | c.*3232T>G | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.236+8046G>A | Intron (SNP) | VAF 87/153 reads (57%) | called by muse, mutect2, varscan2
- TMBIM1 | c.-40-3776C>T | Intron (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- TMEM30A | c.*727T>C | 3'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- TMSB4X | c.-80G>A | 5'UTR (SNP) | VAF 100/101 reads (99%) | catalogued as COSV66081349; called by muse, mutect2, varscan2
- TRAF5 | c.*1901T>A | 3'UTR (SNP) | VAF 96/99 reads (97%) | called by muse, mutect2, varscan2
- TRIML2 | c.*45del | 3'UTR (DEL) | VAF 188/450 reads (42%) | catalogued as COSV100456188; called by mutect2, pindel, varscan2
- TSPYL4 | c.*691T>C | 3'UTR (SNP) | VAF 67/138 reads (49%) | called by muse, mutect2, varscan2
- UQCRC1 | chr3:48609663 C>G | 5'Flank (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- VWC2L | c.*2729T>A | 3'UTR (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- WAC | c.42-19T>C | Intron (SNP) | VAF 14/14 reads (100%) | called by muse, varscan2
- WDR26 | c.928-42C>G | Intron (SNP) | VAF 84/89 reads (94%) | called by muse, mutect2, varscan2
- WDR36 | c.*1009A>G | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- WNT3A | c.*1707A>T | 3'UTR (SNP) | VAF 121/125 reads (97%) | called by muse, mutect2, varscan2
- XPR1 | c.*5118A>C | 3'UTR (SNP) | VAF 138/180 reads (77%) | called by muse, varscan2
- XPR1 | c.*5180A>G | 3'UTR (SNP) | VAF 142/196 reads (72%) | called by muse, varscan2
- ZBTB5 | c.*2413T>C | 3'UTR (SNP) | VAF 32/58 reads (55%) | called by mutect2, varscan2
- ZFHX3 | c.*2466A>T | 3'UTR (SNP) | VAF 108/205 reads (53%) | called by muse, mutect2, varscan2
- ZNF121 | c.*3496C>G | 3'UTR (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- ZNF490 | c.*305G>C | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, varscan2
